Surgical pathology report (de-identified scan), TCGA case TCGA-5N-A9KI, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5N-A9KI-01A (Primary Tumor).

Slides of a cystectomy with attached uterus and adjunct tissue from a poorly differentiated Urothelial Carcinoma with in situ components as well angio and lymphangio invasion with invasion of both ovaries, the uterus and cervix. Ureter is free of tumor.

Classification pTNM 2010:

Stage: pT4a NX L1 V1 Pn1

Grade: G3

R-Classification: R0

ICD-O: 8120/3.

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder NOS
C67.9
JW 5/9/14

Criteria	hw 1/6/14	Yes	No

Source: NCI Genomic Data Commons file cdf20327-221a-4f54-80a3-17430d84d681 (TCGA-5N-A9KI.9F2417E9-F7F7-480E-86C8-A5CD1D54CD73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).